Surgical pathology report (de-identified scan), TCGA case TCGA-24-2262, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2262-01A (Primary Tumor).

[page 1 of 4]
Name:
Address:

MR No.:
Service:
Surgeons:

Surg. Path. No.:
DOB:
Sex/Race:
Location:
Hosp. No.:
Taken/Received:

TCGA-24-2262

DIAGNOSIS

OVARY, RIGHT, TOTAL HYSTERECTOMY AND BILATERAL
SALPINGO-OOPHORECTOMY - POORLY DIFFERENTIATED
ADENOCARCINOMA (SEE COMMENT)

UTERUS, CERVIX, LEFT FALLOPIAN TUBE AND OVARY, TOTAL HYSTERECTOMY
AND BILATERAL SALPINGO-OOPHORECTOMY - POORLY DIFFERENTIATED
ADENOCARCINOMA (SEE COMMENT)

PERITONEUM, ANTERIOR, BIOPSY - SUTURE GRANULOMA
- NO EVIDENCE OF MALIGNANCY

PERITONEUM, SIDEWALL, BIOPSY - POORLY DIFFERENTIATED METASTATIC
ADENOCARCINOMA (SEE COMMENT)

PELVIS, LYMPH NODE, RIGHT - ONE OF ONE LYMPH NODE PRESENT SHOW
METASTATIC ADENOCARCINOMA
- SOFT TISSUE INVOLVEMENT WITH
ADENOCARCINOMA

PELVIS, LYMPH NODE, RIGHT - METASTATIC ADENOCARCINOMA IN SOFT
TISSUES
- NO LYMPH NODES IDENTIFIED

LIVER, BIOPSY - METASTATIC ADENOCARCINOMA

OMENTUM - NO HISTOPATHOLOGIC ABNORMALITY

PELVIS, LYMPH NODE, LEFT - METASTATIC ADENOCARCINOMA IN SOFT
TISSUE
- NO LYMPH NODE IDENTIFIED

SPECIMEN(S) SUBMITTED

Part 1: ANTERIOR PERITONEAL BIOPSY
Part 2: UTERUS/CERVICAL/LEFT OVARY
Part 3: SIDEWALL PERITONEAL BIOPSY
Part 4: RIGHT PELVIC LYMPH NODE
Part 5: RIGHT PELVIC LYMPH NODE SEPARATE
Part 6: TRU-CUT LIVER BIOPSY

[page 2 of 4]
SPECIMEN(S) SUBMITTED

Part 7: OMENTUM
Part 8: LEFT PELVIC LYMPH NODE
Part 9: FS1 OVARY RIGHT OOPHARECTOMY
Part 10: X1 OVARY

HISTORY

The patient is a [REDACTED] G5, P1, SAB4, white [REDACTED] with complex pelvic mass, adenocarcinoma and ascites. Clinical diagnosis: Same as above. Operative procedure: EUA, exploratory laparotomy, TAH/BSO, omentectomy, various biopsies.

FROZEN

FS: Ovary, right, oophorectomy
- "Poorly differentiated carcinoma consistent with ovarian primary" by [REDACTED]

GROSS

The specimens are received in nine containers, each labelled with the patient's name. The first specimen is received fresh, labeled with the patient's name and "frozen section." The specimen consists of two rectangular fragments of tissue measuring, the larger 1.3 x 0.6 cm. Multiple small white nodules are present in the fragments of tissue. The specimen is entirely submitted in one cassette. [REDACTED]

The second container is labeled "anterior peritoneal biopsy." The specimen consists of a white, fibrous fragment of tissue with two small purple nodules. The fragment of tissue measures 0.5 x 0.2 cm. The specimen is entirely submitted in one cassette. Labeled [REDACTED]

The third specimen is received in formalin and labeled "right ovary." The specimen consists of an ovary measuring 10 x 4 x 3 cm. The lesion appears cystic and after opening, uniloculated cyst containing clear fluid is present. The wall is rubbery and range in thickness from 0.1 to 0.3 cm. Multiple papillary areas that in some areas are very prominent are identified. One of the areas in the lesion is markedly solid measuring 0.9 x 0.3 cm with areas of congestion and multiple small white nodules diffusely present around all of these solid areas. Some of the nodules present in the interior of the cyst extend to the external aspect of the ovary. Representative sections are submitted in eight

[page 3 of 4]
Surg. Path. No.:

Name: 1

GROSS (continued)

cassettes from 2A to 2H

The third specimen is received in formalin and labeled "uterus and cervix, and left ovary." The specimen consists of a uterus measuring 10 x 7 x 2 cm and weighing 210 grams. The left fallopian tube and left ovary is attached to the uterus. The right adnexa were amputated previously intraoperatively. Externally, the uterus is globoid in shape and multiple pink-yellow, firm nodules are present in the serosa of the uterus, covering the anterior and posterior aspect of the uterus. Also, externally, a firm yellow-white mass with grossly areas of necrosis is present surrounding the area of the right parametrium. The cervix measures 3 x 2 cm and the ectocervix is grossly unremarkable. After opening, the endometrial cavity measures 7 cm in length and is covered by a slightly irregular pink-yellow endometrium. After sectioning, the myometrial wall measures up to 6 cm and multiple yellow-white, poorly circumscribed nodules are present, ranging in size from 0.1 to 0.6 cm. The endometrial cavity is symmetrical in shape. The left fallopian tube measures 6.5 cm externally tortuous with two small pink-yellow nodules present in the serosa. After sectioning, the lumen appears pinpoint and unremarkable. The left ovary measures 3 x 2 x 1.2 cm and externally is unremarkable. After sectioning, a gray-white irregular stroma is identified. The right fallopian tube is not present in this specimen. Representative sections are submitted in eleven cassettes. Labeled A, cervix, anterior; B, cervix posterior; C and D, anterior endometrium; E and F, posterior endometrium; G and H, right parametrium; I, ovary; J, fallopian tube; K, serous aspect of the endometrium. All of these cassettes are labeled part 3.

The fourth specimen is received in formalin, labeled "side wall, peritoneal biopsy." The specimen consists of a fragment of soft tissue measuring 3 x 1 x 0.2 cm. The tissue appears fibrotic and markedly congested with small white-gray nodules. The specimen is entirely submitted in two cassettes.

The fifth specimen is received in formalin, labeled "right pelvic lymph node." The specimen consists of a fragment of adipose tissue measuring 6 x 2 cm and weighing 11 grams. Some areas of the specimen appear congested and after resection, firm elongated lymph node measuring 0.2 x 0.1 cm is identified. Representative sections are submitted in two cassettes.

The sixth specimen is received in formalin and labeled "right pelvis, lymph nodes." The specimen consists of four fragments of tissue, three of them are gray and rubbery, and range in size from

[page 4 of 4]
GROSS (continued)

0.3 to 0.5 cm. Also, a clot measuring 0.6 x 0.2 cm is present. The specimen is entirely submitted in two cassettes.

The seventh specimen is received in formalin and labeled "Tru-Cut liver biopsy." The specimen consists of a very thin fragment of tissue measuring 1.5 x 0.1 cm. Half of the specimen appears brown in color and the rest is white. The specimen is entirely submitted in one cassette.

The eighth specimen is received in formalin and labeled "omentum." The specimen consists of a segment of omentum measuring 16 x 6 cm and weighs 48 grams. The specimen consists of soft adipose tissue that grossly appears unremarkable. No nodules are identified. Representative sections are submitted in two cassettes.

The ninth specimen is received in formalin and labeled "left pelvic lymph node." The specimen consists of a brown-gray lymph node measuring 0.2 x 0.1 cm. The specimen is entirely submitted in one cassette.

COMMENT

Widespread poorly differentiated adenocarcinoma with a mixture of patterns including solid, glandular, clear and serous papillary is present. Because of the size and histological features, we feel that the tumor originated in the right ovary. There is extension and metastasis to the uterine serosa, myometrium, endometrium, both fallopian tubes, parametrium, left ovary, cervix, multiple biopsies and right pelvic lymph node. Metastatic adenocarcinoma is also present in the liver biopsy. The grade of the tumor is 4 of 4.

(End of Report)

Source: NCI Genomic Data Commons file 2718831c-71f6-466d-9f7d-c72f56312005 (TCGA-24-2262.D58B58AC-365C-43D0-A893-0BECFB6E9FFF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).